Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8M5, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8M5-01A (Primary Tumor).

[page 1 of 2]
Operative Procedure:

Thymectomy

Pre-Operative Diagnosis:

Thymoma

Post-Operative Diagnosis:

Not given

Specimen(s) Received:

Thymus, thymoma

ICD O-3
Thymoma, type B3, malignant
8585/3
Site: Thymus C37.9
2016/10/14

Other Case Numbers :

Final Pathologic Diagnosis:

Thymus, thymectomy:

Thymoma, predominately epithelioid, with microscopic extension beyond capsule. B3 per TSS

Maximum tumor dimension is 6 cm.

Tumor comes to within 0.5 mm of resection margin focally but is not identified at inked margin.

No lymphovascular channel invasion identified.

This case material was reviewed by the pathologist of record and represents the diagnosis of the staff pathologist.

Gross Description:

[page 2 of 2]
Received fresh and subsequently submitted in formalin, after obtaining a portion for tissue procurement, is an 11 x 8 x 2 cm and 91 g piece of fatty tissue. There is a palpable 6 x 4 x 2 cm mass. The lesion is bisected to reveal a tan-pink fleshy mass weighing 51 g. The mass appears to be encapsulated. The fatty tissue is palpated and step-sectioned to reveal no other masses. Sample sections of the mass and surrounding capsule, as well as a sample of the apparently normal fatty tissue are submitted in cassettes 1-8.

Microscopic Description:

A microscopic examination of the thymic mass reveals confluent nests of neoplastic cells with mildly pleomorphic nuclei with open chromatin and small nucleoli. A variable amount of eosinophilic cytoplasm is present, and some tumor cells appear slightly spindled. Small lymphocytes are interspersed among the nests of tumor. The tumor is surrounded by a fibrous capsule, but microscopic extension of the tumor through the capsule is identified. Mitotic figures are not readily identified. Foci of necrotic material with cholesterol clefts are present. At the periphery there is unremarkable fibrofatty tissue with benign thymic remnants. The tumor comes to within 0.5 mm of the surgical margin focally but is not present at the inked margin.

Taken: DOB: (Age: Gender: F Race: White

Criteria	lw 11/5/13	Yes	No
Diagnostic Discrepancy			✓
Staging Discrepancy			✓
Prior M. Significance History			✓
Dual Synchrony: Primary, Metastatic			✓

Source: NCI Genomic Data Commons file d69fab83-932c-4af3-8bc4-41ca6c9180d3 (TCGA-X7-A8M5.735FDAB4-E2DE-4CFF-83DC-42C132B715CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).